Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6885, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6885-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Multiple organ resection – Segment of the large intestine**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis:

Examination performed on:

Macroscopic description:

A 17 cm length of intestine with fat tissue of 1.7 cm in thickness. Ulcerous tumour sized 3 x 4 x 1.2 cm found in the mucosa. The lesion surrounds 80% of the intestine circumference and narrows its lumen, is located 11 cm from the proximal incision line and 2.6 cm from the distal line. Minimum side margin is 0.7 cm.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae.

Incision lines free of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (No II / XIII).

Infiltratio carcinomatosa capsulae lymphonodi et telae adiposae perinodalis.

Histopathological Diagnosis:

Adenocarcinoma tubulare recti. Tubular adenocarcinoma of the rectum.

Metastases carcinomatosae lymphonodis regionalis. Cancer metastases in regional lymph nodes. (No II / XIII). (G2, Dukles C, Astler-Coller C2, pT3, pN1b, R0).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 2066e344-a1b7-4c82-9234-8d8b2a107b67 (TCGA-EI-6885.B16C75F8-9021-447E-9EBE-6EB26727C427.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).